Gene-level copy-number profile of tumor specimen TCGA-BS-A0U9-01B from TCGA case TCGA-BS-A0U9, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 59.1 years (21,580 days).
Specimen TCGA-BS-A0U9-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.e17cff3b-72d9-4e46-8c9b-fddc81452f6c.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BS-A0U9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 404 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/356c9ea2-a028-4eba-86c3-87770a43e910

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 537; copy number 1: 3; copy number 2: 11,714; copy number 3: 16,608; copy number 4: 16,693; copy number 5: 9,002; copy number 6: 573; copy number 7: 2,993; copy number 8: 1,334; copy number 9: 476; copy number 10: 20; copy number 11: 175; copy number 12: 91.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BS-A0U9-01B-21D-A10L-01): tumor purity 0.83, ploidy 3.54, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–143,825,837, 14 genes: AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1.
- chr19:43,192,702–43,269,530, 3 genes (within-gene range 0–5): PSG4, CEACAMP10, PSG9.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 762 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:173,039,960–175,045,648, 45 genes, copy number 9: TNFSF18, GOT2P2, AL022310.1, TNFSF4, AL645568.2, AL645568.1, PRDX6-AS1, PRDX6, SLC9C2, AL139142.1, AL139142.2, ANKRD45, TEX50, KLHL20, BX248409.1, RN7SKP160, CENPL, Y_RNA, DARS2, GAS5, GAS5-AS1, ZBTB37, SERPINC1, RNA5SP67, RC3H1, RNA5SP68, RC3H1-IT1, LINC02776, RPL30P1, RABGAP1L-DT, RABGAP1L, AL022400.1, GPR52, BANF1P4, NDUFAF4P4, Z99127.2, RABGAP1L-IT1, Z99127.1, RABGAP1L-AS1, RNU6-307P, Z99127.3, CACYBP, MRPS14, Y_RNA, ENTR1P2.
- chr3:55,166,910–56,621,837, 15 genes, copy number 9: AC092059.1, LINC02017, LINC02030, AC121764.2, AC121764.3, WNT5A, WNT5A-AS1, AC121764.1, ERC2, AC025572.1, ERC2-IT1, MIR3938, RN7SKP45, RNA5SP133, CCDC66.
- chr3:187,796,187–188,154,057, 7 genes, copy number 12: AC108681.1, AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2.
- chr3:188,178,543–188,180,812, 1 gene, copy number 12: FLJ42393.
- chr6:35,737,032–36,232,790, 14 genes, copy number 9–10 (within-gene range 4–10): ARMC12, AL157823.1, CLPSL2, CLPSL1, CLPS, LHFPL5, SRPK1, SLC26A8, DPRXP2, MAPK14, Z95152.1, MAPK13, Z84485.1, BRPF3.
- chr7:35,036,836–36,841,373, 43 genes, copy number 9: AC005400.1, DPY19L2P1, S100A11P2, TBX20, AC009531.1, AC007652.3, AC007652.2, AC007652.1, AC018647.3, HERPUD2, AC018647.2, AC018647.1, SEPTIN7-DT, AC007551.1, SEPTIN7, AC007551.2, RNU6-1085P, AC087072.1, SEPTIN7P3, PPP1R14BP4, AC083864.5, AC083864.2, AC083864.4, AC083864.1, AC083864.3, MARK2P13, AC078841.1, EEPD1, AC007327.1, AC007327.2, AC006960.1, AC006960.3, KIAA0895, Y_RNA, ANLN, AC006960.2, AOAH, AOAH-IT1, AC007349.4, AC007349.1, AC007349.3, NPM1P18, AC007349.2.
- chr8:33,604,856–37,406,724, 38 genes, copy number 9 (within-gene range 6–9): AF279873.3, BUD31P1, RN7SL457P, VENTXP5, AF279873.2, AF279873.1, AF279873.4, AC087855.2, AC090993.1, AC087855.1, RPL10AP3, LINC01288, AC087343.1, AC099685.1, UNC5D, AC090740.1, LSM12P1, AC105230.1, AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2, AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2.
- chr8:37,784,191–43,378,510, 145 genes, copy number 11 (within-gene range 3–11) (broad region; genes not listed).
- chr8:84,162,118–85,977,154, 39 genes, copy number 9: TPM3P3, AC012400.1, RALYL, RNU6-1040P, PSMC2P2, AC009901.1, AC009901.2, ACTBP6, JCHAINP1, AC091175.1, LRRCC1, AC011773.4, E2F5, AC011773.1, RBIS, CA13, AC011773.3, AC011773.2, CA1, CA3, CA3-AS1, CA2, AC084734.1, AC093331.1, REXO1L8P, REXO1L3P, REXO1L1P, REXO1L12P, REXO1L11P, REXO1L10P, REXO1L9P, REXO1L2P, AC232323.1, REXO1L4P, REXO1L5P, REXO1L6P, AC100801.1, LINC02849, AC100801.2.
- chr8:96,068,729–101,669,726, 124 genes, copy number 9–11 (broad region; genes not listed).
- chr8:101,686,547–101,689,093, 1 gene, copy number 11: AP000426.1.
- chr8:102,417,979–111,040,372, 117 genes, copy number 9–10 (within-gene range 8–10) (broad region; genes not listed).
- chr8:112,222,928–113,436,939, 1 gene, copy number 9 (within-gene range 8–9): CSMD3.
- chr8:112,538,889–123,042,302, 89 genes, copy number 9 (broad region; genes not listed).
- chr14:18,333,726–19,957,996, 83 genes, copy number 12 (within-gene range 5–12) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
